Gene-level copy-number profile of tumor specimen MP2PRT-PAVITN-TMP1-A from MP2PRT case MP2PRT-PAVITN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,492 days).
Specimen MP2PRT-PAVITN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33729ff6-3d87-4c94-9d0e-abbed23a4941.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVITN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/b5fd6c6f-4a00-40b1-af58-927943dbb0f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 436; copy number 1: 3,821; copy number 2: 54,560; copy number 3: 81; copy number 4: 6.

Homozygous deletions (total copy number 0; autosomes only): 436 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,311,460–87,459,044, 4 genes (within-gene range 0–1): AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943.
- chr2:88,857,161–89,234,912, 37 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:90,114,838–90,221,384, 9 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr2:127,294,212–127,388,465, 3 genes: AC068282.1, MAP3K2, RNU6-1147P.
- chr2:136,199,114–136,233,245, 2 genes: HNRNPKP2, AC112255.1.
- chr3:112,332,347–112,499,472, 3 genes (within-gene range 0–2): CD200, AC092894.1, BTLA.
- chr6:108,798,929–108,974,476, 6 genes: Z95118.2, Z95118.1, ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1.
- chr6:108,998,482–108,999,125, 1 gene (within-gene range 0–2): AL390208.1.
- chr7:38,257,879–38,318,861, 8 genes (within-gene range 0–1): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,641,746–142,802,748, 28 genes: TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr11:46,743,048–47,767,443, 42 genes (within-gene range 0–2): CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA.
- chr14:22,147,995–22,552,156, 90 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,762,588, 171 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:92,819,540–92,899,701, 1 gene (within-gene range 0–2): CHASERR.
- chr22:22,032,745–22,245,515, 31 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 965. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
